Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5526, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5526-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] of PSA value of 14.3 on proscar. The patient also has a history of biopsy which reveals poorly differentiated prostatic adenocarcinoma of the right base Gleason 4+ 4 = 8.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

TCGA - EJ - 5526

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -

- A. METASTATIC CARCINOMA SEEN IN ONE OF TWENTY LYMPH NODES EXAMINED (1/20).
- B. EXTRACAPSULAR EXTENSION BY THE TUMOR IS SEEN.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN 7 LYMPH NODES EXAMINED (0/7).

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 4 = 8.
- B. TERTIARY PATTERN 5 CARCINOMA IS SEEN AND ACCOUNTS FOR 1% OF THE TOTAL TUMOR VOLUME.
- C. THE CARCINOMA INVOLVES BOTH LOBES AND IS MULTIFOCAL.
- D. THE TUMOR HAS A GREATEST NODULAR DIAMETER OF 2.5 cm.
- E. THE CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE VOLUME.
- F. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- G. EXTRACAPSULAR EXTENSION IS SEEN IN THE RIGHT ANTERIOR BASE (SLIDES 3U, 3V AND 3W) AND POSTERIOR RIGHT MID (SLIDE 3KK).
- H. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- I. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- J. PERINEURAL INVASION IS IDENTIFIED.
- K. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3a N1 Mx.
- M. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC SEVERELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	95%
WEIGHT OF PROSTATE:	156.19gm
TUMOR SIZE:	Maximum dimension: 2.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	27
LYMPH NODES POSITIVE:	1
EXTRANODAL EXTENSION:	Yes
SIZE OF NODAL METASTASIS:	4mm
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 07ddefbe-0c01-4be4-99b2-fbdc616da626 (TCGA-EJ-5526.5AFEEEBA-2A19-4042-ACDC-8DAD10CA31F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).